Gene-level copy-number profile of tumor specimen TCGA-A7-A0D9-01A from TCGA case TCGA-A7-A0D9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 37.9 years (13,836 days).
Specimen TCGA-A7-A0D9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.3338d4d6-755c-446a-ae7f-7da3bfaf68af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A0D9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcdd6364-1324-4a23-981c-7a572def58c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,378; copy number 2: 47,757; copy number 3: 3,986; copy number 4: 945; copy number 5: 141; copy number 6: 156; copy number 7: 197; copy number 8: 221; copy number 9: 100; copy number 10: 301; copy number 11: 171; copy number 12: 167; copy number 13: 41; copy number 14: 24; copy number 19: 89; copy number 20: 91; copy number 22: 4; copy number 24: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A0D9-01A-31D-A059-01): tumor purity 0.8, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,747 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,672,195–39,838,289, 91 genes, copy number 11–20 (broad region; genes not listed).
- chr8:40,298,697–40,897,833, 4 genes, copy number 22 (within-gene range 1–22): SIRLNT, AC105999.1, AC010857.1, ZMAT4.
- chr8:41,032,892–41,650,817, 17 genes, copy number 19: RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3.
- chr8:41,660,441–41,660,508, 2 genes, copy number 19: MIR486-1, MIR486-2.
- chr8:41,803,349–41,803,450, 1 gene, copy number 20: Y_RNA.
- chr8:46,028,804–52,976,116, 98 genes, copy number 6 (broad region; genes not listed).
- chr8:55,067,585–55,081,909, 1 gene, copy number 7: AC084834.1.
- chr8:55,135,203–55,164,727, 2 genes, copy number 7: AC022679.2, AC022679.1.
- chr8:87,540,835–88,019,113, 7 genes, copy number 6: AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1.
- chr8:103,371,538–145,066,685, 612 genes, copy number 6–10 (broad region; genes not listed).
- chr15:59,871,511–71,063,989, 258 genes, copy number 10–19 (broad region; genes not listed).
- chr15:71,110,244–71,115,494, 1 gene, copy number 14: CT62.
- chr15:71,792,638–73,368,958, 47 genes, copy number 11: NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42, NEO1, FKBP1AP2, NPM1P43, AC068397.1, HCN4, AC068397.2.
- chr15:75,355,207–79,472,304, 123 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr15:95,463,587–99,916,818, 88 genes, copy number 5–24 (broad region; genes not listed).
- chr17:58,755,854–58,985,179, 1 gene, copy number 5 (within-gene range 3–5): PPM1E.
- chr17:58,897,776–59,281,343, 18 genes, copy number 5: AC100832.1, Metazoa_SRP, AC100832.2, TRIM37, RN7SL716P, AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17.
- chr20:47,859,788–50,321,342, 66 genes, copy number 6–13 (broad region; genes not listed).
- chr20:51,386,957–64,313,132, 310 genes, copy number 5–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,378. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
